Somatic mutation profile of tumor specimen TARGET-40-PALWWX-01A (aliquot TARGET-40-PALWWX-01A-01D) from TARGET case TARGET-40-PALWWX, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.2 years (4,464 days).
Specimen TARGET-40-PALWWX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbaa78b0-cb28-4713-be63-bbf1281383d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALWWX-10A (Blood Derived Normal), aliquot TARGET-40-PALWWX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d3f89f3-2aa3-40b4-9a1a-420f6d68a739

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, RNA 4, Nonsense Mutation 3, Splice Site 2, Intron 1, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2
- HRH3 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); catalogued as rs766607043; called by muse, mutect2, varscan2
- NOLC1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as rs1370185935, COSV64181125; called by muse, mutect2
- SCN4A | c.3006G>C p.W1002C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs777574815, COSV71126845; called by muse, varscan2
- TSC2 | c.4662+1G>T p.X1554_splice | Splice Site (SNP) | VAF 200/304 reads (66%) | catalogued as CS078645; called by muse, mutect2, varscan2
- ATP1B1 | c.579T>A p.N193K | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AURKB | c.-25-2A>C | Splice Site (SNP) | VAF 26/36 reads (72%) | called by muse, mutect2, varscan2
- C1S | c.1805A>T p.K602I | Missense Mutation (SNP) | VAF 149/231 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CAP2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- CLIC6 | c.1432G>A p.G478S (on ENST00000360731 / NM_001317009.2; = p.G460S on NM_053277.3) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- DNAH3 | c.7538A>G p.D2513G | Missense Mutation (SNP) | VAF 179/275 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPPA2 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KRT78 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 144/225 reads (64%) | called by muse, mutect2, varscan2
- OR4C11 | c.863_877del p.R288_V292del | In Frame Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- TBL2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TBX22 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM52 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 288/625 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- UNC79 | c.1007C>G p.P336R (on ENST00000393151 / NM_001346218.2; = p.P159R on NM_020818.5) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13A | c.4614G>T p.W1538C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ANXA8L1 | c.291C>T p.Y97= | Silent (SNP) | VAF 157/838 reads (19%) | catalogued as rs1380669748; called by muse, mutect2, varscan2
- CFAP157 | c.591G>A p.L197= | Silent (SNP) | VAF 22/309 reads (7%) | catalogued as rs376783072; called by muse, mutect2
- CHRNA4 | c.1839G>T p.G613= | Silent (SNP) | VAF 79/288 reads (27%) | catalogued as COSV64721306; called by muse, mutect2, varscan2
- FZD6 | c.1452A>G p.L484= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- KCNA5 | c.1545C>T p.I515= | Silent (SNP) | VAF 151/781 reads (19%) | catalogued as rs1429404337, COSV52904695; called by muse, mutect2, varscan2
- KIAA1755 | c.126G>T p.G42= | Silent (SNP) | VAF 104/323 reads (32%) | catalogued as COSV54074357; called by muse, mutect2, varscan2
- AL162431.2 | n.71A>C | RNA (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- MAP3K7CL | chr21:29085846 A>T | 5'Flank (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1473G>T | RNA (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- PRDM11 | c.657-6300C>A | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- PSG6 | c.-44C>T | 5'UTR (SNP) | VAF 25/257 reads (10%) | called by muse, mutect2, varscan2
- SERPINA13P | n.953T>A | RNA (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- SPDYE7P | n.547T>G | RNA (SNP) | VAF 32/502 reads (6%) | called by muse, mutect2
